Somatic mutation profile of tumor specimen 0DK97W from CCDI case PBBUCL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (975 days).
Specimen 0DK97W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff21c7b-a46b-4776-837e-30fa6829b57e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK96D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe01297c-f4ef-4027-8c10-f1ad5f7af79d

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STIM1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 221/480 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs200907515; called by muse, mutect2, varscan2
- MRC2 | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 103/696 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF518A | c.2333T>C p.F778S | Missense Mutation (SNP) | VAF 40/752 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2
- FSD1 | c.666C>T p.I222= | Silent (SNP) | VAF 32/693 reads (5%) | catalogued as rs772809988, COSV55698360; called by muse, mutect2
